Somatic mutation profile of tumor specimen TARGET-10-PAPHED-09A (aliquot TARGET-10-PAPHED-09A-01D) from TARGET case TARGET-10-PAPHED, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (755 days).
Specimen TARGET-10-PAPHED-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af445ff5-798d-4b0d-ab1f-0c51c5a4569b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHED-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHED-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecdc2b10-2fd6-4de6-a0fc-b0a5dc15d151

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 3, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>C p.G636R (on ENST00000288602 / NM_001374244.1; = p.G596R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GLI3 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as CM050640, COSV67895633; called by muse, mutect2, varscan2
- NID1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs200279383, COSV99937045; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCH2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV64709843; called by muse, mutect2, varscan2
- SIGLEC14 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1243555512; called by muse, mutect2, varscan2
- THSD7B | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs781503094, COSV55706486; called by muse, mutect2, varscan2
- TOR3A | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs777406110; called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031467 del CATTCACACAGTGACAC | Missense Mutation (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel*
- LRRC9 | c.4073C>T p.S1358L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZXDC | c.1600A>G p.N534D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NRXN1 | c.492C>T p.A164= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs201180707, COSV68012172, COSV68024889; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PAK5 | c.42G>A p.P14= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as rs370805526, COSV62041063; called by muse, mutect2, varscan2
- PTCH1 | c.1164C>T p.N388= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs201602238, COSV100109417, COSV59493086; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF418 | c.264C>A p.G88= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- ASCC3 | c.*4G>A | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- CPPED1 | c.289+13T>C | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- MAST4 | c.674+17222G>A | Intron (SNP) | VAF 3/18 reads (17%) | catalogued as rs912286294; called by muse, mutect2
- MCM7 | c.-8C>G | 5'UTR (SNP) | VAF 11/64 reads (17%) | catalogued as COSV57999806; called by muse, mutect2, varscan2
- SLC25A45 | c.153+24T>A | Intron (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
